Surgical pathology report (de-identified scan), TCGA case TCGA-61-2092, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2092-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LEFT ADNEXA, MASS, LEFT SALPINGO-OOPHORECTOMY –

- A. PAPILLARY SEROUS CARCINOMA, HIGH-GRADE, ASSOCIATED WITH SEROUS CYSTADENOMA OF OVARY (see comment).
- B. THE TUMOR IS UNILATERAL (LEFT OVARY).
- C. SEROSAL SURFACE IS INVOLVED BY TUMOR GROSSLY.
- D. FALLOPIAN TUBE IS NOT INVOLVED.

PART 2: RIGHT SIDEWALL TUMOR, BIOPSY –

METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING INFARCTED FIBROUS TISSUE.

PART 3: UTERUS, CERVIX, RIGHT ADNEXA, HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY –

- A. ENDOMETRIAL POLYP.
- B. INACTIVE ENDOMETRIUM.
- C. LEIOMYOMATA (4.0 CM).
- D. BENIGN CERVIX WITH CHRONIC INFLAMMATION.
- E. UNREMARKABLE OVARY AND FALLOPIAN TUBE.

PART 4: LYMPH NODE, LEFT, ILIAC, EXCISION –

ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 5: LYMPH NODES, INTERNAL AND EXTERNAL ILIAC, EXCISION –

FIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/5).

PART 6: LYMPH NODE, LEFT OBTURATOR, EXCISION –

ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: ANTERIOR CUL-DE-SAC, BIOPSY –

METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING INFARCTED FIBROUS TISSUE.

PART 8: LYMPH NODE, RIGHT, ILIAC, EXCISION –

ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 9: LYMPH NODES, RIGHT INTERNAL AND EXTERNAL ILIAC, EXCISION –

SIX LYMPH NODES, NEGATIVE FOR TUMOR (0/6).

PART 10: LYMPH NODES, RIGHT OBTURATOR, EXCISION –

METASTATIC ADENOCARCINOMA INVOLVING ONE OUT OF FOUR LYMPH NODES (1/4).

PART 11: LYMPH NODE, RIGHT PERIAORTIC, EXCISION –

ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 12: LYMPH NODES, LEFT PERIAORTIC, EXCISION –

THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 13: OMENTUM, OMENTECTOMY –

BENIGN FIBROADIPOSE TISSUE WITH REACTIVE MESOTHELIAL HYPERPLASIA AND CHRONIC INFLAMMATION.

Source: NCI Genomic Data Commons file 4e8447db-1dec-4ec5-bf27-7a8740c15f11 (TCGA-61-2092.35B4BFA3-E6A5-4B55-A7F1-BC39953422C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).